Somatic mutation profile of tumor specimen TCGA-RW-A689-01A (aliquot TCGA-RW-A689-01A-11D-A35D-08) from TCGA case TCGA-RW-A689, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 58.6 years (21,402 days).
Specimen TCGA-RW-A689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae90cd80-bf76-427f-93c0-28feabeb623c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A689-10A (Blood Derived Normal), aliquot TCGA-RW-A689-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53dae8af-66e8-4ef4-a7d8-8d090641e2c9

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RSRC2 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV59202993; called by muse, mutect2, varscan2
- WNT9B | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1431848216; called by muse, mutect2, varscan2
- ANO3 | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL2L14 | c.607+1G>A p.X203_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CMYA5 | c.7918C>G p.L2640V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KLHL7 | c.1319G>T p.G440V (on ENST00000339077 / NM_001031710.3; = p.G392V on NM_018846.5) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.4593del p.G1532Efs*42 (on ENST00000358273 / NM_001042492.3; = p.G1511Efs*42 on NM_000267.3) | Frame Shift Del (DEL) | VAF 40/74 reads (54%) | called by mutect2, pindel, varscan2
- OAZ3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- ADGRE3 | c.1188G>A p.S396= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs190395132; called by muse, mutect2, varscan2
- INPP4A | c.1470G>A p.S490= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs374359971; called by muse, varscan2
